Somatic mutation profile of tumor specimen TCGA-A6-A56B-01A (aliquot TCGA-A6-A56B-01A-31D-A28G-10) from TCGA case TCGA-A6-A56B, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 57.2 years (20,903 days).
Specimen TCGA-A6-A56B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d425813e-a5b0-4456-8b26-f71f327914ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-A56B-10A (Blood Derived Normal), aliquot TCGA-A6-A56B-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52ca4fa5-0663-4685-b1a2-0f346204c554

The open-access MAF lists 104 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 23, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AF196969.1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs28935174, CD033706, CM990499, COSV99339273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.112del p.Q38Kfs*6 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs1555526795, CM107390, COSV52689258; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TPSD1 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 21/222 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs3865205, COSV52973780; called by muse, mutect2
- ACER1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs374412423; called by muse, mutect2, varscan2
- ALK | c.3626G>A p.R1209Q | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs747643140, COSV101201977, COSV66557012; called by muse, mutect2, varscan2
- APC | c.4190del p.E1397Gfs*18 | Frame Shift Del (DEL) | VAF 64/108 reads (59%) | catalogued as COSV57378145; called by mutect2, pindel, varscan2
- ARSB | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1457848169; called by muse, mutect2, varscan2
- BCORL1 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 86/103 reads (83%) | catalogued as COSV54389030; called by muse, mutect2, varscan2
- C1R | c.991G>A p.E331K (on ENST00000536053 / NM_001354346.2; = p.E317K on NM_001733.7) | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs772306231, COSV73293776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC110 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780508472; called by muse, mutect2, varscan2
- COBL | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767027309; called by muse, mutect2, varscan2
- COL11A2 | c.4538G>A p.R1513Q (on ENST00000341947 / NM_080680.3; = p.R1406Q on NM_080679.2) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs371674362; called by muse, mutect2, varscan2
- COPG1 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779788008, COSV59113943; called by muse, mutect2, varscan2
- EPHB6 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 106/209 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752688738, COSV63890450, COSV63890523; called by muse, mutect2, varscan2
- ERMN | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68075136; called by muse, mutect2, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FBN3 | c.8419C>A p.Q2807K | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.097); catalogued as COSV53664060; called by muse, mutect2, varscan2
- FOLH1 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV57045280, COSV57050085, COSV99923881; called by muse, mutect2, varscan2
- GNAO1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.892); catalogued as rs200127285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIBADH | c.852G>C p.K284N | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753848362; called by muse, mutect2, varscan2
- HYDIN | c.7523G>A p.R2508H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs376601468; called by muse, mutect2, varscan2
- IGSF5 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs751303291, COSV66031603; called by muse, mutect2, varscan2
- IRGC | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as rs56159111, COSV54986117; called by muse, mutect2, varscan2
- KAZN | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1191998283, COSV101055625; called by muse, mutect2, varscan2
- KIAA0895 | c.350A>G p.E117G (on ENST00000297063 / NM_001100425.2; = p.E66G on NM_015314.3) | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.409); catalogued as COSV51709925, COSV51710320; called by muse, mutect2, varscan2
- KIAA2026 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs754732111, COSV67354492; called by muse, mutect2, varscan2
- LMO3 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs145877643; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- METTL15 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57724175; called by muse, mutect2, varscan2
- MTA3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV65922071; called by muse, mutect2, varscan2
- MUC16 | c.37687C>T p.R12563C | Missense Mutation (SNP) | VAF 118/338 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs780625713, COSV67463430; called by muse, mutect2, varscan2
- MYH1 | c.2689G>C p.A897P | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1254514196, COSV56853392; called by muse, mutect2, varscan2
- NIPBL | c.8257C>T p.R2753C | Missense Mutation (SNP) | VAF 77/107 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs186140730; called by muse, mutect2, varscan2
- NRAP | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs752825681, COSV63489506; called by muse, mutect2, varscan2
- OR2J1 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV65850445; called by muse, mutect2, varscan2
- OR2J1 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.582); catalogued as rs777091944, COSV65850450; called by muse, mutect2, varscan2
- P4HTM | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as COSV59088987; called by muse, mutect2, varscan2
- PHOSPHO2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs753729243, COSV55868928, COSV55870160; called by muse, mutect2, varscan2
- PIAS4 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53681025; called by muse, mutect2
- PIK3AP1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs201086332; called by muse, mutect2, varscan2
- PLAG1 | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as COSV57614746; called by muse, mutect2, varscan2
- PLD2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200449808, COSV54009508; called by muse, mutect2, varscan2
- POTEH | c.413G>C p.W138S | Missense Mutation (SNP) | VAF 104/496 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.393); catalogued as COSV100625222; called by muse, mutect2, varscan2
- PRPF8 | c.3502G>C p.V1168L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100517040; called by muse, mutect2, varscan2
- SLTM | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as rs760892608; called by muse, mutect2, varscan2
- SPTBN5 | c.2698G>A p.G900S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as rs140057818, COSV100311586, COSV58019809; called by muse, mutect2, varscan2
- STYK1 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs375423751; called by muse, mutect2, varscan2
- TANC2 | c.3583G>A p.V1195I | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs750422428, COSV67331538; called by muse, mutect2, varscan2
- THBS2 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs781033084; called by muse, mutect2, varscan2
- TMCC2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs745395559, COSV58002916; called by muse, mutect2, varscan2
- TMEM181 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs752419674, COSV100892624; called by muse, mutect2
- TRIM24 | c.1739C>G p.T580S (on ENST00000343526 / NM_015905.3; = p.T546S on NM_003852.4) | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as COSV58977744; called by muse, mutect2, varscan2
- TTC21B | c.3165G>A p.W1055* | Nonsense Mutation (SNP) | VAF 42/107 reads (39%) | catalogued as COSV99692297; called by muse, mutect2, varscan2
- TXLNB | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs370843595; called by muse, mutect2, varscan2
- ZBTB4 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.921); catalogued as rs775889094; called by muse, mutect2, varscan2
- ZMIZ1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); catalogued as COSV57905016; called by muse, mutect2, varscan2
- AADACL4 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCC8 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 234/352 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ACSM5 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- APMAP | c.776del p.P259Rfs*31 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP26 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- BCHE | c.401A>T p.N134I | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2
- DOCK4 | c.3401+4A>T | Splice Region (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- HMMR | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- IGHE | c.851T>A p.L284Q | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MORC1 | c.2933dup p.N978Kfs*2 | Frame Shift Ins (INS) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- PATE1 | c.71C>A p.S24* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.2837C>T p.T946I | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- PRKAG1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RTL3 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SEC16A | c.576dup p.D193* | Frame Shift Ins (INS) | VAF 21/105 reads (20%) | called by mutect2, pindel, varscan2
- TSPAN12 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- UBE2U | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR87 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ZNF22 | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ZNF799 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZP1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ARNT2 | c.699G>A p.S233= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs767002088, COSV57586156; ClinVar: likely benign; called by muse, mutect2, varscan2
- C1R | c.2031G>A p.P677= (on ENST00000536053 / NM_001354346.2; = p.P663= on NM_001733.7) | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs147540938; called by muse, mutect2, varscan2
- CA5A | c.720C>T p.T240= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as rs547918689, COSV59241907; called by muse, mutect2, varscan2
- CILP | c.447G>A p.E149= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs542219859, COSV99973881; called by muse, mutect2, varscan2
- CREB5 | c.336C>T p.P112= (on ENST00000357727 / NM_182898.4; = p.P105= on NM_004904.3) | Silent (SNP) | VAF 73/424 reads (17%) | catalogued as rs370145745, COSV63228941; called by muse, mutect2, varscan2
- DPP9 | c.1563G>A p.T521= (on ENST00000598800; = p.T550= on NM_139159.5) | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as rs780220422; called by muse, mutect2, varscan2
- GRM1 | c.897C>A p.L299= | Silent (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- IZUMO1R | c.321C>A p.I107= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- KCNJ12 | c.687C>T p.R229= | Silent (SNP) | VAF 35/171 reads (20%) | catalogued as rs569037483, COSV59163450; called by muse, mutect2, varscan2
- L3MBTL2 | c.198C>G p.T66= | Silent (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- LVRN | c.504C>T p.N168= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as rs752634994, COSV63497645; called by muse, mutect2, varscan2
- MAGEB1 | c.168C>A p.G56= | Silent (SNP) | VAF 54/76 reads (71%) | called by muse, mutect2, varscan2
- NGEF | c.402G>A p.P134= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV50945695; called by muse, mutect2, varscan2
- NLRP8 | c.1053C>T p.L351= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs267605703, COSV52585055; called by muse, mutect2, varscan2
- OPRK1 | c.621C>T p.V207= | Silent (SNP) | VAF 100/190 reads (53%) | called by muse, mutect2, varscan2
- OPRM1 | c.903C>T p.Y301= | Silent (SNP) | VAF 155/320 reads (48%) | catalogued as rs200986335, COSV57676566, COSV57682130; called by muse, mutect2, varscan2
- PCDHA6 | c.213C>T p.R71= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV100972473; called by muse, mutect2, varscan2
- PCDHA9 | c.2037G>A p.S679= | Silent (SNP) | VAF 55/240 reads (23%) | catalogued as rs140380568, COSV65324356; called by muse, mutect2, varscan2
- PGAP1 | c.1062G>T p.V354= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- PLD1 | c.129C>T p.D43= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs145417719; called by muse, mutect2
- PLD2 | c.279C>T p.H93= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs759364410, COSV54009484; called by muse, mutect2, varscan2
- SEC31A | c.3081G>A p.P1027= (on ENST00000355196 / NM_001318120.1; = p.P988= on NM_016211.4) | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs144285817, COSV52341750; called by muse, mutect2, varscan2
- ZFAND2B | c.207G>T p.G69= | Silent (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- FKBP6 | c.-180G>A | 5'UTR (SNP) | VAF 49/214 reads (23%) | catalogued as rs1462426559, COSV99334298; called by muse, mutect2, varscan2
- KAT8 | c.1312+20G>A | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, varscan2
- MIR323A | n.24C>T | RNA (SNP) | VAF 83/170 reads (49%) | catalogued as rs777341661; called by muse, mutect2, varscan2
- MLLT10 | c.240+17927_240+17971del | Intron (DEL) | VAF 28/124 reads (23%) | called by mutect2, pindel
